Somatic mutation profile of tumor specimen 0DO2FL from CCDI case PBCBZB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.3 years (3,037 days).
Specimen 0DO2FL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f54987e5-a370-4a5a-829c-49a74c13015d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DO2EP (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e301de1a-6c64-49c8-a9b2-f7718575ff36

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 2, Intron 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FARP1 | c.556A>G p.I186V | Missense Mutation (SNP) | VAF 40/682 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs750565094; called by muse, mutect2
- NEB | c.15029G>A p.R5010Q | Missense Mutation (SNP) | VAF 66/1002 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs781250495, COSV50828547; called by muse, mutect2
- SETD1B | c.4556C>T p.P1519L | Missense Mutation (SNP) | VAF 22/381 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.051); catalogued as rs1206117924; called by muse, mutect2
- KMT2C | c.14072dup p.Y4691* | Nonsense Mutation (INS) | VAF 99/611 reads (16%) | called by mutect2, varscan2
- MCM4 | c.1831A>T p.T611S | Missense Mutation (SNP) | VAF 32/763 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.687); called by muse, mutect2
- ZNF184 | c.528dup p.G177Rfs*5 | Frame Shift Ins (INS) | VAF 296/686 reads (43%) | called by mutect2, varscan2
- MYO3A | c.3069G>A p.L1023= | Silent (SNP) | VAF 48/1395 reads (3%) | called by muse, mutect2
- PITX3 | c.624C>T p.T208= | Silent (SNP) | VAF 9/222 reads (4%) | called by muse, mutect2
- NMNAT1 | c.115+77T>C | Intron (SNP) | VAF 8/166 reads (5%) | called by muse, mutect2
